Somatic mutation profile of tumor specimen 0DCBJ8 from CCDI case PBBLFW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,925 days).
Specimen 0DCBJ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a336764-b925-4cfd-ac87-065c14b3aaf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCBIU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8265f4-2248-4bfc-8338-2135e42d5ff5

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 111/299 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 74/191 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397509344, COSV61005273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 460/506 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERICH3 | c.3799G>C p.V1267L | Missense Mutation (SNP) | VAF 309/674 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs757559200, COSV100443380, COSV58616922; called by muse, mutect2, varscan2
- RET | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 248/535 reads (46%) | catalogued as COSV60690613; called by muse, mutect2, varscan2
- UTRN | c.7870C>G p.R2624G | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as rs1422078523; called by muse, mutect2, varscan2
- ZNF727 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs1409998864; called by muse, varscan2
- ATRX | c.2765del p.D922Vfs*48 | Frame Shift Del (DEL) | VAF 300/436 reads (69%) | called by mutect2, pindel, varscan2
- CDC42EP4 | c.581C>G p.P194R | Missense Mutation (SNP) | VAF 20/487 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2
- KALRN | c.2242G>C p.D748H | Missense Mutation (SNP) | VAF 40/689 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMPO | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 232/563 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBLCP1 | c.507T>A p.F169L | Missense Mutation (SNP) | VAF 19/409 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VLDLR | c.2579A>G p.Y860C | Missense Mutation (SNP) | VAF 14/526 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ALG6 | c.1266C>A p.S422= | Silent (SNP) | VAF 165/389 reads (42%) | catalogued as rs748902317; called by muse, mutect2, varscan2
- PACS1 | c.1272C>G p.L424= | Silent (SNP) | VAF 25/464 reads (5%) | called by muse, mutect2
- ZNF202 | c.1737G>A p.A579= | Silent (SNP) | VAF 264/608 reads (43%) | catalogued as rs760478791; called by muse, mutect2, varscan2
- FOLH1 | c.640-11G>A | Intron (SNP) | VAF 74/165 reads (45%) | catalogued as rs1452754105; called by muse, mutect2, varscan2
- THAP8 | c.*32G>C | 3'UTR (SNP) | VAF 42/793 reads (5%) | catalogued as rs762737730, COSV99495766; called by muse, mutect2
